Gene-level copy-number profile of tumor specimen TCGA-20-0990-01A from TCGA case TCGA-20-0990, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.4 years (27,170 days).
Specimen TCGA-20-0990-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.54231a5f-a9b2-471b-88c8-05cf5e04dca1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-20-0990-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ba9734b-e7e3-4a4a-8f20-76957db9d6ce

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,269; copy number 2: 22,216; copy number 3: 21,971; copy number 4: 9,101; copy number 5: 843; copy number 6: 1,878; copy number 7: 559; copy number 8: 573; copy number 9: 319; copy number 10: 20; copy number 12: 26; copy number 14: 4; copy number 19: 18; copy number 20: 7; copy number 21: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-20-0990-01): tumor purity 0.88, ploidy 3, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,533 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,640,157–39,969,968, 164 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr1:55,329,288–56,070,513, 1 gene, copy number 7 (within-gene range 6–7): AL603840.1.
- chr1:55,398,514–56,645,301, 13 genes, copy number 7 (within-gene range 5–7): RNU6-830P, Y_RNA, LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85.
- chr3:135,925,891–136,752,403, 12 genes, copy number 8 (within-gene range 6–8): AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10.
- chr3:172,039,578–172,821,474, 17 genes, copy number 7 (within-gene range 6–7): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P.
- chr3:187,423,315–198,222,513, 235 genes, copy number 7–9 (broad region; genes not listed).
- chr6:54,602,487–54,945,099, 7 genes, copy number 7: RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1.
- chr6:64,377,795–64,733,837, 3 genes, copy number 8: AL357375.1, HNRNPDP2, AL355357.1.
- chr6:87,000,045–90,587,072, 75 genes, copy number 7–10 (broad region; genes not listed).
- chr6:99,432,325–100,890,338, 19 genes, copy number 8–12: USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2.
- chr6:101,430,411–101,454,245, 2 genes, copy number 8: ACTG1P18, AP002528.1.
- chr6:104,017,633–107,459,564, 50 genes, copy number 7–12 (within-gene range 1–12): R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr8:115,950,511–117,540,262, 19 genes, copy number 8–14 (within-gene range 3–14): LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16.
- chr8:119,730,774–122,127,184, 24 genes, copy number 8–21: TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3.
- chr8:127,578,473–129,683,770, 19 genes, copy number 14–19 (within-gene range 4–19): AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26.
- chr16:52,005,487–52,280,638, 8 genes, copy number 7: C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22.
- chr16:52,436,772–52,437,474, 1 gene, copy number 7: AC007490.1.
- chr16:69,741,871–70,373,383, 25 genes, copy number 8 (within-gene range 3–8): NOB1, AC092115.1, WWP2, SNORA62, MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1, PDPR, AC009060.1, CLEC18C, AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4.
- chr19:7,348,943–15,742,343, 478 genes, copy number 8 (broad region; genes not listed).
- chr19:17,555,649–24,163,425, 316 genes, copy number 7–9 (broad region; genes not listed).
- chr19:28,790,812–31,147,981, 44 genes, copy number 7: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1.
- chr19:31,167,457–31,225,143, 1 gene, copy number 7: LINC01791.

Autosomal genes at a single copy (total copy number 1): 1,844. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
